Gene-level copy-number profile of tumor specimen C3N-03093-03 from CPTAC case C3N-03093, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; Tumor grade: G3.
Specimen C3N-03093-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3d10d5d1-7a3e-411b-9c1f-23dfd70a95d8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03093-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/d022f6b7-0346-4f6e-9960-5a2100fadc55

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 71; copy number 2: 57,867; copy number 3: 406; copy number 4: 33; copy number 5: 21; copy number 8: 6.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 27 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:101,129,077–102,628,070, 27 genes, copy number 5–8 (within-gene range 2–8): PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1.

Autosomal genes at a single copy (total copy number 1): 71. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
